Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RN-01A (Primary Tumor).

[page 1 of 7]
PAGE: 1

RUN DATE:
RUN TIME:
BY:

Specimen Inquiry

PATIENT: ACCT #: LOC: U#:
AGE/SX: /F RM/BED: REG:
REG DR: STATUS: TLOC: DIS:

SPEC #: Obtained: Subm Dr: MD
STATUS: Received:

CLINICAL HISTORY:

PELVIC PAIN; CERVICAL CANCER

SPECIMEN/PROCEDURE:

1. LYMPH - LEFT COMMON ILIAC
2. LYMPH - LEFT PELVIC NODES
3. LYMPH - RIGHT COMMON ILIAC
4. SOFT TISSUES OF ABDOMEN - RIGHT PARAMETRIAL NODULE
5. LYMPH - RIGHT PARA AORTIC
6. LYMPH - RIGHT PELVIC NODES
7. UTERUS - W/ CERVIX, BILAT TUBES AND OVARIES

1CD-0-3
carcinoma, squamous cell, large cell,
keratinizing 8071/3
Site: cervix, NOS C53.9
lw
9/8/11

IMPRESSION:

- 1) LYMPH NODES, LEFT COMMON ILIAC, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 2) LYMPH NODES, LEFT PELVIC, REGIONAL DISSECTION:
. Five benign lymph nodes (0/5).
- 3) LYMPH NODE, RIGHT COMMON ILIAC, BIOPSY:
. One benign lymph node (0/1).
- 4) SOFT TISSUE, RIGHT PARAMETRIAL NODULE, BIOPSY:
. Benign fibrotic calcified nodule.
- 5) LYMPH NODES, RIGHT PARA-AORTIC, REGIONAL DISSECTION:
. Two benign lymph nodes (0/2).
- 6) LYMPH NODES, RIGHT PELVIC, REGIONAL DISSECTION:
. Metastatic squamous cell carcinoma, microscopic focus, involving one of four lymph nodes (1/4).
. Histologically, the metastatic focus is 2.5 mm in greatest histologic extent.
- 7) UTERUS WITH CERVIX AND BILATERAL TUBES AND OVARIES; RADICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
. CERVIX:
. Invasive squamous cell carcinoma, keratinizing large cell type, moderately differentiated; See Checklist.

** CONTINUED ON NEXT PAGE **

[page 2 of 7]
IMPRESSION: (continued)

- . Invasive carcinoma circumferentially involves the cervical canal and invades the outer half of the cervical stroma; invasive carcinoma invades to a depth of 15.5 mm of 16.0 mm total cervical stromal thickness (97%).
- . Lymphovascular space invasion is identified.
- . Squamous cell carcinoma in situ with endocervical gland extension is also identified.
- . Invasive carcinoma is present 0.5 mm from the deep (radial) cervical stromal margin of resection.
- . PARAMETRIUM, RIGHT:
- . Metastatic squamous cell carcinoma, microscopic focus.
- . PARAMETRIUM, LEFT:
- . Benign fibroadipose and vascular tissue.
- . One benign lymph node (0/1).
- . VAGINAL CUFF WITH MARGIN:
- . Squamous mucosa with patchy mild to moderate chronic inflammation.
- . No diagnostic evidence of significant dysplasia or malignancy.
- . ENDOMETRIUM:
- . Atrophic changes; negative for endometrial hyperplasia or malignancy.
- . MYOMETRIUM:
- . Adenomyosis.
- . UTERINE SEROSA:
- . Negative for malignancy.

*Pathologic TNM (AJCC 6th Edition): pT2b pN1 pM0

CERVICAL CARCINOMA CHECKLISTMACROSCOPICSPECIMEN TYPE

Radical hysterectomy

TUMOR SITE

Right superior quadrant
Right inferior quadrant
Left superior quadrant
Left inferior quadrant

TUMOR SIZE

Greatest dimension: 2.8 cm
Additional dimensions: 1.4 x 1.1 cm

OTHER ORGANS PRESENT

Right ovary
Left ovary

** CONTINUED ON NEXT PAGE **

[page 3 of 7]
IMPRESSION: (continued)

Right fallopian tube
Left fallopian tube
Vaginal cuff

MICROSCOPICHISTOLOGIC TYPE

Squamous cell carcinoma
Keratinizing

HISTOLOGIC GRADE

G2: Moderately differentiated

EXTENT OF INVASIONPRIMARY TUMOR (pT)TNM (FIGO)

pT2 (II): Tumor invades beyond the uterus but not to pelvic wall or to lower third of vagina

pT2b (IIB): Tumor with parametrial invasion.

REGIONAL LYMPH NODES (pN)

pN1: Regional lymph node metastasis

Number examined: 15

Number involved: 1

DISTANT METASTASIS (pM)

pMX: Cannot be assessed

MARGINS

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 0.5 mm from the deep (radial) cervical margin of resection.

Carcinoma in situ absent at distal vaginal cuff margin

DEPTH OF INVASION

The maximal thickness of the cervical stromal invasion is 15.5 mm.

The thickness of the cervix in the area of maximal tumor invasion is 16.0 mm.

The percentage of cervical stromal invasion is 97%.

Parametrial involvement

Parametrial involvement on the right side only.

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L)

Present

ADDITIONAL PATHOLOGIC FINDINGS

** CONTINUED ON NEXT PAGE **

[page 4 of 7]
IMPRESSION: (continued)

Squamous cell carcinoma in situ with endocervical gland extension
Adenomyosis, myometrium
Endometriosis, microscopic focus, left parametrium

Dictated

Entered:

SPECIAL STAINS/PROCEDURES:

The following immunoperoxidase stain is performed with appropriate positive and negative controls on block 7N:

CD31:

highlights endothelial-lined spaces filled with tumor (supports the impression of lymphovascular space invasion).

Dictated by:

GROSS DESCRIPTION:

- 1) Received labeled with the patient's name and "left common iliac". Received is a portion of yellow gold to pink tan fibroadipose tissue that is, 2.5 x 1.8 x 0.9 cm. Specimen is dissected for possible lymph nodes. Three possible lymph nodes identified, ranging from 0.6 to 0.9 cm in greatest dimension. Specimen is submitted as follows:

CASSETTE SUMMARY:

CASSETTE 1A: Three possible lymph nodes.

- 2) Received labeled with the patient's name and "left pelvic lymph node". Received is a portion of yellow gold to pink tan fibroadipose tissue that is, 4.5 x 3 x 1.2 cm. Specimen is dissected for possible lymph nodes. Five possible lymph nodes identified, ranging from 0.7 to 2.5 cm in greatest dimension. Submitted as follows:

CASSETTE SUMMARY:

Cassette 2A: Two possible lymph nodes.
Cassette 2B: One lymph node bisected.
Cassette 2C: One lymph node serially sectioned.
Cassette 2D: One lymph node trisected.

- 3) Received labeled with the patient's name and "right common iliac". Received is a yellow gold to purple tan portion of fibroadipose tissue that is, 1.7 x 1.4 x 0.3 cm. Specimen is dissected for possible lymph nodes. One lymph node is grossly identifiable that is, 1 x 0.5 x 0.5 cm.

** CONTINUED ON NEXT PAGE **

[page 5 of 7]
GROSS DESCRIPTION: (continued)**CASSETTE SUMMARY:**

Cassette 3A: One lymph node bisected.

- 4) Received labeled with the patient's name and "parametrial nodule". Received is a white to pale pink tan tissue fragment that is, 0.8 x 0.5 x 0.5 cm. Specimen is bisected and reveals a pale yellow tan calcified fragment. The specimen is entirely submitted in cassette 4A.
- 5) Received labeled with the patient's name and "right para-aortic". Received is a portion of yellow gold to pink tan slightly hemorrhagic fibroadipose tissue that is, 4 x 1 x 1 cm. Two possible lymph nodes identified, ranging from 1.5 to 2 cm in greatest dimension.

CASSETTE SUMMARY:

Cassette 5A: One lymph node bisected.

Cassette 5B: One lymph node bisected.

- 6) Received labeled with the patient's name and "right pelvic lymph node". Received is a 3.2 x 3 x 1.2 cm aggregate of yellow gold slightly hemorrhagic fibroadipose tissue. Dissected for possible lymph nodes. Four possible lymph nodes identified, ranging from 0.5 to 2.1 cm in greatest dimension. Submitted as follows:

CASSETTE SUMMARY:

Cassette 6A: Two possible lymph nodes.

Cassette 6B: One lymph node bisected.

Cassette 6C: One lymph node bisected.

- 7) Received fresh, labeled with the patient's name, medical record number and "uterus, cervix, bilateral tubes and ovaries", is a 86 gram specimen including an unopened uterus (7.0 x 5.0 x 3.0 cm), with attached vaginal cuff (1.1 cm in length), and right and left parametrium each one measuring 5.0 x 4.0 x 0.3 cm, right fallopian tube (5.0 cm in length x 0.6 cm in diameter), right ovary (2.2 x 1.0 x 0.9 cm), left fallopian tube (4.8 cm in length x 0.7 cm in diameter), and left ovary (1.9 x 1.0 x 0.9 cm). There is a 2.8 x 1.4 x 1.1 cm white-tan to gray centrally ulcerated mass involving both anterior and posterior surface of the cervix. The mass appears to invade the outer half of the cervical stroma to a depth of 1.0 cm and encroaches upon the deep (radial) cervical margin of resection; the tumor is 0.8 cm from the vaginal cuff margin that is grossly free of tumor. The external os is distorted by the mass. The endometrial cavity (4.0 cm from cornu to cornu, 3.8 cm in length), has a tan-pink endometrium (0.3 cm in average thickness). The myometrium measures 1.4 cm in maximum thickness. The serosa is glistening and has adhesions on the posterior surface. The fallopian tubes are patent and have fimbriated ends. Both ovaries have tan-white smooth surface and multiple corpora albicantia. Representative sections are submitted as follows:

CASSETTE SUMMARY:

** CONTINUED ON NEXT PAGE **

[page 6 of 7]
GROSS DESCRIPTION: (continued)

Cassette 7A: Vaginal cuff margin, 9:00-1:00, en face.
Cassette 7B, 7C: Vaginal cuff margin, 1:00-4:00, perpendicular.
Cassette 7D: Vaginal cuff margin, 4:00-6:00, en face.
Cassette 7E: Vaginal cuff margin, 6:00-9:00, en face.
Cassette 7G, 7H: Cervix and lower uterine segment, 12:00, bisected and submitted from proximal to distal in two cassettes.
Cassette 7J-7L: Cervix and lower uterine segment, 6:00, trisected and submitted from proximal to distal in three cassettes.
Cassette 7M: 2:00.
Cassette 7N: 5:00.
Cassette 7P: 8:00.
Cassette 7Q: 11:00.
Cassette 7R, 7S: Anterior endomyometrium.
Cassette 7T, 7U: Posterior endomyometrium.
Cassette 7V: Right ovary and right fallopian tube.
Cassette 7W: Left ovary and left fallopian tube.
Cassette 7X-7BB: Right parametrium, entirely submitted.
Cassette 7CC-7HH: Left parametrium, entirely submitted.
Cassette 7RN: Additional fallopian tube for research.
Cassette 7RT: Additional endometrial tumor for research.

Dictated:

Entered:

COPIES TO:

CPT Codes:

CD31-88342/ LYMPH NODE, REGIONAL RESECT/88307/
UTERUS W/WO ADNEXAE, TUMOR-88309/ LYMPH NODE BIOPSY (1-4)/88305/
SOFT TISSUE BIOPSY (1-4)/88305/

** CONTINUED ON NEXT PAGE **

[page 7 of 7]
SPEC #:

Continued) Page: 7

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 87b40f35-b4ff-4b1a-9ccb-0b8a4f87fcd0 (TCGA-EK-A2RN.5B78C1A5-1A21-4970-8CB9-54B6D7C5F672.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).